Gene-level copy-number profile of tumor specimen TCGA-AP-A5FX-01A from TCGA case TCGA-AP-A5FX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 68.6 years (25,063 days).
Specimen TCGA-AP-A5FX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.a81f2e88-d57f-4368-8f65-9e1738d8da39.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AP-A5FX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a1f7c16d-8de6-4429-975d-702346d35360

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 16; copy number 2: 1,268; copy number 3: 9,919; copy number 4: 23,228; copy number 5: 16,728; copy number 6: 3,271; copy number 7: 4,308; copy number 8: 453; copy number 9: 142; copy number 10: 151; copy number 11: 71; copy number 12: 22; copy number 13: 26; copy number 14: 49; copy number 16: 8; copy number 18: 39; copy number 24: 89.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AP-A5FX-01A-11D-A27O-01): tumor purity 0.68, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.
- chr10:87,500,337–88,787,061, 28 genes: AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 597 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:64,470,129–65,641,559, 24 genes, copy number 9: CACHD1, MIR4794, RAVER2, JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1.
- chr1:83,790,280–85,578,363, 41 genes, copy number 9 (within-gene range 6–9): AL035706.1, TTLL7, TTLL7-IT1, AC104454.1, AC104454.2, AL359504.1, PRKACB, TXN2P1, NEDD8P1, AL359273.1, SAMD13, AL359273.2, UOX, DNASE2B, AL844170.1, RPF1, GNG5, AL359762.3, SPATA1, CTBS, AL359762.1, AL359762.2, LINC01555, AC114482.1, SSX2IP, AC104169.1, LPAR3, MCOLN2, DNAI3, MCOLN3, MIR4423, AL603750.1, SYDE2, C1orf52, Y_RNA, BCL10, AL078459.1, DDAH1, Y_RNA, AL360219.1, AC092807.3.
- chr2:85,315,041–85,791,383, 33 genes, copy number 9: AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, PARTICL, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68, SFTPB, GNLY, GPR160P1, RNU1-38P, ATOH8, MIR6071.
- chr3:51,385,291–51,704,323, 8 genes, copy number 11: MANF, RBM15B, DCAF1, RAD54L2, RNU6ATAC29P, TEX264, AC099050.1, RNA5SP132.
- chr3:168,902,194–169,038,416, 4 genes, copy number 18: LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr6:75,237,675–75,919,537, 22 genes, copy number 11 (within-gene range 7–11): COX7A2, TMEM30A, TMEM30A-DT, FILIP1, HMGB1P39, AL445465.1, U3, MIR4463, AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20, H3P27, RNU6-1338P, SENP6, AL356057.1, RNU6-1016P, RN7SKP163, AL109897.1, MYO6, RNU6-155P, RNA5SP209.
- chr6:109,978,256–111,047,521, 26 genes, copy number 13: GPR6, AL590009.1, WASF1, CDC40, METTL24, AL050350.1, DDO, SLC22A16, RN7SL617P, AC002464.1, AL512430.3, AL512430.4, CDK19, AL512430.1, AL512430.2, AL603914.1, RNU6-957P, SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1, AL357515.1, GTF3C6, RPF2, GSTM2P1.
- chr6:151,494,017–152,637,801, 10 genes, copy number 12 (within-gene range 7–12): CCDC170, RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1, SYNE1, SYNE1-AS1, AL049548.1, RNA5SP223.
- chr6:157,700,387–157,945,077, 6 genes, copy number 10 (within-gene range 7–10): SNX9, AL391863.2, AL391863.1, SNX9-AS1, HSPE1P26, RNU6-786P.
- chr8:39,451,045–40,520,158, 19 genes, copy number 11: ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1.
- chr8:53,851,795–53,959,303, 1 gene, copy number 11 (within-gene range 7–11): RGS20.
- chr8:53,914,719–54,871,720, 21 genes, copy number 11 (within-gene range 7–11): RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7, RP1, SEC11B, AC090151.1.
- chr8:119,873,717–120,373,573, 4 genes, copy number 12 (within-gene range 7–12): DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr10:120,925,547–121,739,730, 9 genes, copy number 9: AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1.
- chr10:123,991,910–124,988,189, 20 genes, copy number 9: YBX2P1, AL683842.1, CHST15, OAT, NKX1-2, AL445237.1, LHPP, RPS10P18, AC068896.1, FAM53B, AL513190.1, FAM53B-AS1, EEF1AKMT2, Y_RNA, ABRAXAS2, Y_RNA, NPM1P31, AL731577.2, ZRANB1, AL731577.1.
- chr10:124,996,064–125,001,491, 1 gene, copy number 9: AL731571.1.
- chr11:19,299,883–20,121,601, 10 genes, copy number 10 (within-gene range 8–10): AC009652.1, NAV2, NAV2-IT1, RNA5SP335, NAV2-AS5, NAV2-AS4, MIR4486, AC023950.1, AC009549.1, MIR4694.
- chr11:74,807,739–83,423,516, 170 genes, copy number 14–24 (within-gene range 2–24) (broad region; genes not listed).
- chr11:83,643,602–83,815,263, 3 genes, copy number 14: DLG2-AS2, AP002370.1, LDHAL6DP.
- chr11:94,706,431–95,132,645, 14 genes, copy number 9 (within-gene range 3–9): AMOTL1, AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1.
- chr16:73,794,057–74,296,762, 7 genes, copy number 10 (within-gene range 5–10): AC087565.2, AC087565.1, AC092128.1, AC138627.1, AC138627.2, AC009120.6, PPIAP49.
- chr17:32,830,219–34,174,964, 16 genes, copy number 12–16 (within-gene range 3–16): Y_RNA, AC084809.1, AC084809.2, TMEM98, SPACA3, ASIC2, AC003687.1, AC008133.2, AC008133.1, AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3.
- chr17:81,681,174–82,212,830, 46 genes, copy number 10: ARL16, HGS, MIR6786, AC139530.3, AC139530.1, MRPL12, AC139530.2, SLC25A10, GCGR, MCRIP1, PPP1R27, P4HB, AC145207.3, AC145207.9, AC145207.2, ARHGDIA, AC145207.5, AC145207.6, ALYREF, ANAPC11, NPB, PCYT2, SIRT7, MAFG, AC145207.8, MAFG-DT, PYCR1, AC145207.4, MYADML2, AC145207.1, NOTUM, AC145207.7, ASPSCR1, CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L, FASN, CCDC57, AC129510.1, AC129510.2.
- chr18:3,571,215–3,656,282, 5 genes, copy number 10: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1.
- chr19:12,433,103–13,633,025, 77 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
